Gene-level copy-number profile of tumor specimen TCGA-CG-4441-01A from TCGA case TCGA-CG-4441, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 83.6 years (30,528 days).
Specimen TCGA-CG-4441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9a3472c1-38b6-4b0f-b75b-afd2f3d350d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4441-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7b00761-3a7a-4f3d-b57b-608ba17190a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 3,246; copy number 2: 51,704; copy number 3: 4,709; copy number 4: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4441-01A-01D-1799-01): tumor purity 0.63, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,218,853–204,377,665, 4 genes (within-gene range 0–2): PLEKHA6, AL592114.3, AL592114.1, LINC00628.
- chr2:27,889,941–28,338,901, 1 gene (within-gene range 0–2): BABAM2.
- chr2:27,996,367–28,310,560, 5 genes: MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34.
- chr2:46,003,942–46,004,309, 1 gene: RPL26P15.
- chr2:62,939,916–63,048,640, 2 genes (within-gene range 0–2): RPS20P9, AC007098.1.
- chr2:160,141,981–160,271,888, 2 genes (within-gene range 0–2): AC092153.1, LINC02478.
- chr2:185,950,469–186,422,432, 4 genes (within-gene range 0–2): AC097500.1, RPL21P32, LINC01473, AC104058.1.
- chr2:235,494,043–236,131,800, 1 gene (within-gene range 0–2): AGAP1.
- chr2:235,773,855–236,072,556, 4 genes: AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P.
- chr3:71,289,769–71,305,853, 1 gene: FOXP1-AS1.
- chr3:119,821,321–120,094,994, 5 genes (within-gene range 0–2): GSK3B, AC092910.4, AC078856.1, AC092910.1, AC092910.2.
- chr3:188,153,284–188,890,671, 1 gene (within-gene range 0–2): LPP.
- chr3:188,562,238–188,688,866, 2 genes: LPP-AS1, MIR28.
- chr4:71,300,258–71,437,924, 2 genes: AC096713.1, LDHAL6EP.
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.
- chr5:60,021,249–60,304,151, 2 genes: AC034234.1, RNU6-806P.
- chr5:108,784,098–108,830,790, 2 genes: AC034207.1, AC008871.1.
- chr7:7,640,752–8,004,053, 1 gene (within-gene range 0–1): AC007161.3.
- chr7:7,906,519–8,094,272, 6 genes: RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:75,409,142–76,560,168, 11 genes (within-gene range 0–2): AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1.
- chr11:96,092,374–96,137,827, 1 gene: AP000779.1.
- chr15:62,390,526–62,844,631, 3 genes (within-gene range 0–2): TLN2, MGC15885, AC100839.1.
- chr17:72,818,836–72,839,718, 2 genes: AC080037.1, AC011120.1.
- chr22:40,044,817–40,335,808, 1 gene (within-gene range 0–2): TNRC6B.
- chr22:40,346,500–40,410,289, 4 genes: ADSL, AL022238.3, SGSM3, SGSM3-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 867. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
